Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6855, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6855-01A (Primary Tumor).

[page 1 of 3]
			Formatted Path Report	
			Colon segment up to 17 cm long with the tumor of 9 cm in its largest dimension; fatty tissue lymph nodes are small, their observation is not enough informative.	Adenocarcinoma; G2; fatty tissue infiltration. Lymph nodes demonstrate reactive changes.

[page 2 of 3]
Tumor Features: Ulcerated, Tumor Extent: Fat, NOS, Venous Invasion: Absent, Margins: Absent, Treatment Effect:	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Sigmoid colectomy Specimen size: Not specified Tumor site: Sigmoid colon Tumor size: 0 x 0 x 9 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: 0/12 positive for metastasis (Adjacent fatty tissue 0/12) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
---	--

Source: NCI Genomic Data Commons file 0da2fd64-2545-4907-bbbd-7c56e8fba5a5 (TCGA-F4-6855.27EE7F05-6980-4F93-ACB4-4D723F1D6FC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).